Gene-level copy-number profile of tumor specimen TCGA-BT-A0S7-01A from TCGA case TCGA-BT-A0S7, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 75.4 years (27,533 days).
Specimen TCGA-BT-A0S7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.00e2a4bb-6ef0-4e36-88ba-d0cb858b55e6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BT-A0S7-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d3f4839e-e6b0-4007-ab2d-132782c8093d

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 187; copy number 1: 37,671; copy number 2: 19,986; copy number 3: 1,380; copy number 5: 562; copy number 21: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BT-A0S7-01A-11D-A10T-01): tumor purity 0.29, ploidy 5.67, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 187 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:26,159,079–26,782,104, 32 genes (within-gene range 0–1): FAM110D, C1orf232, AL391650.1, ZNF593, CNKSR1, CATSPER4, ZPLD2P, AL355877.2, CEP85, AL355877.1, SH3BGRL3, UBXN11, CD52, CRYBG2, AL451139.1, ZNF683, LIN28A, DHDDS, AL513365.1, DHDDS-AS1, HMGN2, DPPA2P2, RPS6KA1, MIR1976, RN7SL679P, Y_RNA, RNU7-29P, AL627313.1, AL627082.2, AL627082.1, AL512408.1, ARID1A.
- chr2:148,595,158–148,825,835, 3 genes: RPS29P8, EPC2, RNU2-9P.
- chr2:228,683,537–228,753,786, 2 genes: AC012070.1, RPL7L1P10.
- chr3:70,751,123–71,754,229, 9 genes (within-gene range 0–1): COX6CP6, HMGB1P36, RNU6-281P, FOXP1, AC097634.4, FOXP1-AS1, MIR1284, AC097634.2, FOXP1-IT1.
- chr3:71,584,943–71,587,409, 1 gene: AC097634.1.
- chr4:4,290,251–5,500,994, 15 genes (within-gene range 0–1): ZBTB49, AC105415.1, NSG1, STX18, STX18-IT1, RPS7P15, STX18-AS1, AC092437.1, LINC01396, MSX1, LDHAP1, RN7SKP113, CYTL1, STK32B, Y_RNA.
- chr8:122,414,332–123,274,284, 25 genes (within-gene range 0–1): SMILR, LINC01151, AC108136.1, AC100872.1, AC100872.2, CDK5P1, AC016405.3, AC016405.2, ZHX2, AC016405.1, AC104316.2, AC104316.1, DERL1, TBC1D31, HMGB1P19, AC068228.3, FAM83A, U3, AC068228.1, AC068228.2, FAM83A-AS1, MIR4663, C8orf76, ZHX1-C8orf76, UBA52P5.
- chr9:21,695,176–22,824,213, 19 genes: KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239.
- chr9:22,747,700–22,768,316, 2 genes: CLIC4P1, AC017067.1.
- chr12:73,159,190–75,984,015, 36 genes (within-gene range 0–1): LINC02444, AC090503.1, AC087879.1, RNU6-1012P, LINC02445, U8, LINC02882, AC136188.1, LINC02394, AC090502.3, AC090502.2, AC090502.1, VENTXP3, ATXN7L3B, AC025257.1, AC123904.2, AC123904.1, AC123904.3, AC073525.1, KCNC2, CAPS2-AS1, CCNG2P1, CAPS2, AC092552.1, AC121761.2, GLIPR1L1, GLIPR1L2, GLIPR1, AC121761.1, KRR1, AC078923.1, AC022507.1, AC078820.2, RPL10P13, SNORA70, AC078820.1.
- chr15:94,455,469–96,842,384, 43 genes: AC009432.2, LINC02852, AC009432.1, AC022308.1, AC087633.2, AC107976.1, AC087633.1, AC087636.1, LINC01197, AC104260.1, AC104260.2, AC104260.3, LINC00924, AC027013.1, AC015574.1, RNU2-3P, AC012409.2, AC024337.1, AC024337.2, NR2F2-AS1, AC012409.5, AC012409.3, AC012409.1, AC012409.4, LINC02157, AC016251.1, NR2F2, MIR1469, AC103746.1, AC087477.2, TUBAP12, AC087477.5, AC087477.3, PGAM1P12, AC087477.1, AC087477.4, RN7SKP254, Metazoa_SRP, AC110588.1, FAM149B1P1, SPATA8-AS1, SPATA8, RN7SKP181.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 1,971 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:165,647,636–166,104,457, 4 genes, copy number 3 (within-gene range 1–3): AC080079.2, AC080079.1, LINC01179, TLL1.
- chr12:68,746,125–69,738,574, 29 genes, copy number 21: SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1.
- chr13:18,467,172–55,174,548, 727 genes, copy number 3 (broad region; genes not listed).
- chr13:56,214,373–98,455,176, 397 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr13:98,329,655–102,402,457, 73 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr13:102,685,744–114,337,626, 179 genes, copy number 3 (broad region; genes not listed).
- chr20:87,250–30,289,956, 562 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 35,250. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
